Somatic mutation profile of tumor specimen MP2PRT-PATXWU-TMP1-A (aliquot MP2PRT-PATXWU-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATXWU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,196 days).
Specimen MP2PRT-PATXWU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67dd80e9-e9e4-42e3-9c0c-4fae1cd6ba27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXWU-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXWU-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6732fdcc-6ab9-46eb-a692-e65e0878f508

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 5'Flank 1, Intron 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.5033C>T p.S1678L | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138753923; called by muse, mutect2, varscan2
- CDYL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346545104, COSV73654985; called by muse, mutect2, varscan2
- KNSTRN | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as rs369930942; called by muse, mutect2, varscan2
- NCAN | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs749169084; called by muse, mutect2
- PLEK2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs777210790; called by muse, mutect2, varscan2
- PTPN5 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as rs144630372; called by muse, mutect2, varscan2
- RNF20 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100874341; called by muse, mutect2
- ARIH1 | c.588G>A p.S196= | Splice Region (SNP) | VAF 13/322 reads (4%) | called by muse, mutect2
- DRC7 | c.2619C>A p.F873L | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, varscan2
- KIF1A | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2
- NDUFA7 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TACC2 | c.6601G>T p.A2201S (on ENST00000334433; = p.A279S on NM_006997.4) | Missense Mutation (SNP) | VAF 66/734 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.71); called by muse, mutect2
- UBE2A | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFR2 | c.543C>T p.A181= | Silent (SNP) | VAF 152/531 reads (29%) | catalogued as rs150598483; called by muse, mutect2, varscan2
- PLD1 | c.2094C>A p.I698= | Silent (SNP) | VAF 30/294 reads (10%) | called by muse, mutect2
- PSME4 | c.4533C>T p.Y1511= | Silent (SNP) | VAF 77/178 reads (43%) | called by muse, mutect2, varscan2
- SDHA | c.552G>A p.G184= | Silent (SNP) | VAF 47/338 reads (14%) | catalogued as rs147444427; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC35D3 | c.387G>A p.S129= | Silent (SNP) | VAF 64/495 reads (13%) | called by muse, mutect2, varscan2
- TLL1 | c.1899C>T p.G633= | Silent (SNP) | VAF 99/354 reads (28%) | called by muse, mutect2, varscan2
- AC139491.3 | chr5:176034593 G>A | 5'Flank (SNP) | VAF 72/178 reads (40%) | catalogued as rs1193250503; called by muse, mutect2, varscan2
- HMGCLL1 | c.632+11A>T | Intron (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
